Somatic mutation profile of tumor specimen TCGA-ZF-A9R3-01A (aliquot TCGA-ZF-A9R3-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9R3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 53.1 years (19,384 days).
Specimen TCGA-ZF-A9R3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28a1aa63-a17a-42d2-ade0-dda4c3a3a296.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R3-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R3-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f0101b7-9709-496e-9a81-8a87a3bbf1a6

The open-access MAF lists 100 somatic variants for this specimen: 70 protein-altering or splice-affecting, 24 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 24, Nonsense Mutation 6, Intron 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, RNA 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 34/49 reads (69%) | catalogued as rs118203631, CM971520, CX024084, COSV53763295; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3497A>T p.E1166V | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV99289198; called by muse, mutect2, varscan2
- ABL2 | c.1582G>A p.D528N (on ENST00000502732 / NM_007314.4; = p.D513N on NM_005158.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs754261724, COSV61013345; called by muse, mutect2, varscan2
- ADAMTS18 | c.3256G>A p.G1086R | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51399208, COSV51413104; called by muse, mutect2, varscan2
- AGTR2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100903609; called by muse, mutect2, varscan2
- ALDH9A1 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 54/120 reads (45%) | catalogued as rs866901450, COSV61341844; called by muse, mutect2, varscan2
- ANKMY2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs764216200, COSV100187281; called by muse, mutect2, varscan2
- AVPR2 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as COSV100509643; called by muse, mutect2
- AXIN2 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 344/370 reads (93%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV100196873; called by muse, mutect2, varscan2
- BRINP2 | c.1235+2T>G p.X412_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100838299; called by muse, mutect2, varscan2
- BRIP1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 93/105 reads (89%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV99370803; called by muse, mutect2, varscan2
- CCDC170 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99498739; called by muse, mutect2, varscan2
- CEP290 | c.2689A>T p.I897L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100469573; called by muse, mutect2, varscan2
- CFAP161 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs1397018220, COSV99715585; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99267775; called by muse, mutect2, varscan2
- CPXCR1 | c.728A>C p.Q243P | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99342378; called by muse, mutect2, varscan2
- CRTAC1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764021235, COSV53997045; called by muse, mutect2, varscan2
- CSMD1 | c.6616G>A p.G2206S (on ENST00000520002; = p.G2205S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766680987, COSV59322798; called by muse, mutect2, varscan2
- CTC1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1333941661, COSV100236704; called by muse, mutect2, varscan2
- CYC1 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100010562; called by muse, mutect2
- CYP51A1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99134068; called by muse, mutect2, varscan2
- DCAF12L2 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1326781748, COSV63584562; called by muse, mutect2, varscan2
- DCLRE1B | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100849834; called by muse, mutect2, varscan2
- DDX10 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV100489866; called by muse, mutect2, varscan2
- DUS1L | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV100152606; called by muse, mutect2, varscan2
- FAM171A1 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100968469; called by muse, mutect2, varscan2
- G2E3 | c.1078A>T p.K360* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99249848; called by muse, mutect2, varscan2
- GATA1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.164); catalogued as rs1317593957, COSV64961764; called by muse, mutect2, varscan2
- GPR158 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893797, COSV100894176; called by muse, mutect2, varscan2
- HARBI1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1565358942, COSV56317837; called by muse, mutect2, varscan2
- IGF1R | c.2542A>G p.I848V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777782407, COSV99159392; called by muse, mutect2, varscan2
- ILDR1 | c.234C>G p.Y78* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99878821; called by muse, mutect2
- ILDR1 | c.232T>A p.Y78N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99878824; called by muse, mutect2
- IQCF1 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100094950; called by muse, mutect2
- KCNMA1 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303770190, COSV99699201; called by muse, mutect2, varscan2
- KDM6A | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100938519, COSV65036910; called by muse, mutect2, varscan2
- LIPJ | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100905923; called by muse, mutect2, varscan2
- LRBA | c.8047G>A p.G2683S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1350202046, COSV100842014; called by muse, mutect2, varscan2
- LUZP4 | c.92A>T p.D31V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100904872; called by muse, mutect2, varscan2
- MGAT3 | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.135); catalogued as rs867840954, COSV100362029, COSV57867867; called by muse, mutect2, varscan2
- NSD3 | c.486G>C p.Q162H | Missense Mutation (SNP) | VAF 105/124 reads (85%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as COSV100388862, COSV57622277; called by muse, mutect2, varscan2
- OR51G2 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432212; called by muse, mutect2, varscan2
- OR6C68 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV101110052; called by muse, mutect2, varscan2
- PCDHA2 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as rs782395206, COSV65364596; called by muse, mutect2, varscan2
- PCDHA9 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100969993; called by muse, mutect2, varscan2
- PCDHGB1 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs762711142, COSV53958443; called by muse, mutect2, varscan2
- PDCL | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 41/62 reads (66%) | catalogued as COSV52343616; called by muse, mutect2, varscan2
- PINK1 | c.1042del p.E348Kfs*16 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV58632473; called by mutect2, pindel, varscan2
- PNPLA6 | c.362C>A p.S121Y (on ENST00000414982 / NM_001166111.2; = p.S73Y on NM_006702.5) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99654334; called by muse, mutect2, varscan2
- PODXL2 | c.1437G>C p.Q479H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51740252, COSV99230067; called by muse, mutect2, varscan2
- PPEF1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV62996723; called by muse, mutect2, varscan2
- RAD1 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV100337591; called by muse, mutect2, varscan2
- RHOB | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RIOX2 | c.1263G>T p.L421F (on ENST00000333396 / NM_001042533.2; = p.L420F on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99477356; called by muse, mutect2, varscan2
- RNF44 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV99221985; called by muse, mutect2
- SLC6A19 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100443601, COSV100443702; called by muse, mutect2, varscan2
- SLC9A8 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1224846238, COSV100846296; called by muse, mutect2, varscan2
- SPG7 | c.1843C>G p.L615V (on ENST00000268704; = p.L622V on NM_003119.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs896570007, COSV99245348; called by muse, mutect2, varscan2
- SYNE1 | c.22901C>T p.S7634L (on ENST00000367255 / NM_182961.4; = p.S7563L on NM_033071.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs147109049; called by muse, mutect2, varscan2
- TRPM4 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs376782481; called by muse, mutect2, varscan2
- UXS1 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs773625425, COSV99308647; called by muse, mutect2, varscan2
- VPS13D | c.11207C>T p.S3736F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV99168010; called by muse, mutect2, varscan2
- WBP4 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101069323; called by muse, mutect2, varscan2
- ZNF337 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99430391; called by muse, mutect2, varscan2
- ZNF404 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1568436154, COSV100182771; called by mutect2, varscan2
- ZNF423 | c.1886C>T p.S629L (on ENST00000563137 / NM_001379286.1; = p.S621L on NM_015069.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV52200600; called by muse, mutect2, varscan2
- ZNF441 | c.1880C>G p.S627* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100777454; called by muse, mutect2, varscan2
- FRMD6 | c.764dup p.I256Nfs*9 (on ENST00000344768 / NM_001267046.2; = p.I248Nfs*9 on NM_152330.4) | Frame Shift Ins (INS) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.15545dup p.L5183Pfs*16 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel
- MYH11 | c.4723del p.Q1575Sfs*52 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- AFMID | c.51G>A p.K17= | Silent (SNP) | VAF 83/124 reads (67%) | catalogued as rs745962259, COSV56960491; called by muse, mutect2, varscan2
- ARHGAP35 | c.174C>T p.L58= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs758568895, COSV101351512; called by muse, mutect2, varscan2
- CNOT1 | c.3417C>G p.V1139= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV55315856, COSV99801009; called by muse, mutect2, varscan2
- COL11A2 | c.3132A>T p.A1044= (on ENST00000341947 / NM_080680.3; = p.A937= on NM_080679.2) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100554420; called by mutect2, varscan2
- DISP2 | c.1497C>T p.I499= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV99140430; called by muse, mutect2, varscan2
- FRY | c.8736G>A p.L2912= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100969795; called by muse, mutect2, varscan2
- GRIK4 | c.849G>A p.Q283= | Silent (SNP) | VAF 87/227 reads (38%) | catalogued as COSV101483709; called by muse, mutect2, varscan2
- HSD17B10 | c.90T>C p.L30= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99395072; called by muse, mutect2, varscan2
- ITIH5 | c.2121C>T p.L707= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1348298926, COSV99905518; called by muse, mutect2, varscan2
- KIAA1549 | c.4614C>T p.R1538= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs373515937; called by muse, varscan2
- LVRN | c.306C>T p.L102= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV63497045; called by muse, mutect2, varscan2
- MED13L | c.4572G>A p.L1524= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99929894; called by muse, mutect2, varscan2
- MRPS14 | c.171C>G p.L57= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV62880933; called by muse, mutect2, varscan2
- PDE6G | c.180G>C p.L60= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100148638; called by muse, mutect2, varscan2
- RNASE11 | c.36C>T p.G12= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs112127139, COSV100250604; called by muse, mutect2, varscan2
- SCRIB | c.450C>T p.L150= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs773591724, COSV57586770, COSV57587494; called by muse, mutect2
- SHTN1 | c.408C>G p.V136= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as rs780107522, COSV99599348; called by muse, mutect2, varscan2
- SLC27A2 | c.1188G>A p.L396= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99983032; called by muse, mutect2, varscan2
- SLC47A2 | c.57C>T p.L19= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1308973187, COSV100328213; called by muse, mutect2, varscan2
- TMPRSS4 | c.591G>A p.G197= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1235406010, COSV71110198; called by muse, mutect2, varscan2
- TNK2 | c.1971G>T p.A657= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs201682144, COSV100361638; called by muse, mutect2, varscan2
- TOX | c.1173T>C p.S391= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100789301; called by muse, mutect2, varscan2
- ZFC3H1 | c.2082T>C p.L694= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1489118581, COSV101110672; called by muse, mutect2, varscan2
- ZNF160 | c.189G>A p.G63= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV62000697; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726146 G>A | 3'Flank (SNP) | VAF 38/47 reads (81%) | catalogued as rs755072448; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2451C>T | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- PAX3 | c.586+425C>T | Intron (SNP) | VAF 72/154 reads (47%) | catalogued as rs372706630; called by muse, varscan2
- SNORA9 | n.104A>G | RNA (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TK1 | c.-27C>A | 5'UTR (SNP) | VAF 14/21 reads (67%) | catalogued as rs1388531910, COSV100015082; called by muse, mutect2, varscan2
- WNK1 | c.2140-2449G>C | Intron (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100268286; called by muse, mutect2, varscan2
